Somatic mutation profile of tumor specimen TCGA-57-1994-01A (aliquot TCGA-57-1994-01A-01W-0894-08) from TCGA case TCGA-57-1994, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 63.1 years (23,062 days).
Specimen TCGA-57-1994-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa46c8f7-c34c-4d95-9b20-9d38a7464587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-57-1994-11A (Solid Tissue Normal), aliquot TCGA-57-1994-11A-01W-0700-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b3407fd-2d0a-4f2a-a68f-060416fa122e

The open-access MAF lists 51 somatic variants for this specimen: 45 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 38, Silent 6, In Frame Del 2, Nonsense Mutation 1, Splice Region 1, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL031777.2 | c.385+5G>A | Splice Region (SNP) | VAF 22/66 reads (33%) | catalogued as rs760402571, COSV100587299; called by muse, mutect2, varscan2
- ANK2 | c.7418C>T p.P2473L | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100003247, COSV100004597; called by muse, mutect2
- BAZ2B | c.5620G>T p.V1874L | Missense Mutation (SNP) | VAF 37/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100601091; called by muse, mutect2
- BMP5 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs538635494, COSV63704659; called by muse, mutect2, varscan2
- CACNA1G | c.3386G>A p.R1129Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1180552980, COSV61734091; called by muse, mutect2
- CDYL2 | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV101629634, COSV73654525; called by muse, mutect2, varscan2
- CFAP157 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV100077125; called by muse, mutect2, varscan2
- CNTNAP2 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as COSV62276161; called by muse, mutect2, varscan2
- CPA4 | c.1030T>A p.S344T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); catalogued as COSV99745415; called by muse, mutect2, varscan2
- DHTKD1 | c.1727C>A p.A576D | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53805809, COSV99537000; called by muse, mutect2
- DSCAM | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV101261700, COSV68026065; called by muse, mutect2, varscan2
- EIF2B5 | c.2089G>C p.D697H (on ENST00000647909; = p.D689H on NM_003907.3) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.744); catalogued as COSV99889569; called by muse, mutect2, varscan2
- ERI3 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 148/326 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV100952279; called by muse, mutect2, varscan2
- GCNT2 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758159782, COSV65458517; called by muse, mutect2, varscan2
- HCLS1 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 170/1156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100101281; called by muse, varscan2
- HRNR | c.5789C>A p.S1930Y | Missense Mutation (SNP) | VAF 54/754 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100914021, COSV64261277; called by muse, mutect2
- KLF15 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99955401; called by muse, mutect2, varscan2
- MCF2 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100645237; called by muse, mutect2
- MDGA2 | c.2604G>A p.M868I (on ENST00000399232 / NM_001113498.2; = p.M570I on NM_182830.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100638694; called by muse, mutect2, varscan2
- OR4S2 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV56748465; called by muse, mutect2, varscan2
- OR5M3 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV56566689; called by muse, mutect2, varscan2
- OVCH1 | c.857A>C p.E286A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.347); catalogued as COSV100549316; called by muse, mutect2, varscan2
- PARD3 | c.3217C>G p.R1073G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100630742, COSV100633538; called by muse, mutect2
- PARD3B | c.1810G>C p.A604P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); catalogued as rs1037351059, COSV100595584; called by muse, mutect2, varscan2
- PASD1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV100949366, COSV64855294; called by mutect2, varscan2
- PKHD1L1 | c.7832T>A p.F2611Y | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101006951; called by muse, mutect2
- PRDM9 | c.1570G>T p.V524F | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV99691114; called by muse, mutect2, varscan2
- RNF10 | c.2253T>A p.D751E | Missense Mutation (SNP) | VAF 26/536 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100379046; called by muse, mutect2
- ROMO1 | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV99488968; called by muse, mutect2, varscan2
- SH3TC2 | c.1810G>T p.D604Y | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.606); catalogued as COSV100102467; called by muse, mutect2
- SLFN11 | c.1947G>C p.E649D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV100391088; called by muse, mutect2, varscan2
- TBX20 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV101282438, COSV68783923; called by muse, mutect2, varscan2
- TG | c.5719G>A p.A1907T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs367688576; called by muse, mutect2, varscan2
- TMEM156 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs572792495, COSV60743919; called by muse, mutect2, varscan2
- TMEM161B | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs764371176, COSV56932881; called by muse, mutect2, varscan2
- TNPO3 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554441599, COSV99603594; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPAN15 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs142068659; called by muse, mutect2, varscan2
- UBQLN1 | c.712-1G>C p.X238_splice | Splice Site (SNP) | VAF 49/296 reads (17%) | catalogued as COSV99973604; called by muse, mutect2, varscan2
- WDR24 | c.514A>T p.N172Y (on ENST00000248142; = p.N110Y on NM_032259.4) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV99556063; called by muse, mutect2, varscan2
- ZNF721 | c.1474T>G p.L492V (on ENST00000338977; = p.L504V on NM_133474.4) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.376); catalogued as COSV100167936; called by muse, mutect2, varscan2
- EPM2AIP1 | c.629_631del p.T210del | In Frame Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- RBBP6 | c.4739_4740del p.K1580Rfs*6 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- SYNPO2 | c.1644_1673del p.S549_S558del | In Frame Del (DEL) | VAF 29/126 reads (23%) | called by mutect2, pindel
- TP53 | c.583dup p.I195Nfs*14 | Frame Shift Ins (INS) | VAF 37/64 reads (58%) | called by mutect2, pindel, varscan2
- ZSCAN5B | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HIPK2 | c.2475C>T p.I825= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV100702633, COSV61230973; called by muse, mutect2, varscan2
- ITCH | c.2482C>T p.L828= (on ENST00000262650 / NM_001257137.3; = p.L787= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV99393278; called by muse, mutect2, varscan2
- KIRREL2 | c.1587G>T p.V529= | Silent (SNP) | VAF 33/742 reads (4%) | catalogued as COSV99384527; called by muse, mutect2
- OMA1 | c.438G>A p.P146= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as rs148414102; called by muse, mutect2
- OR2G6 | c.828T>A p.L276= | Silent (SNP) | VAF 48/80 reads (60%) | catalogued as COSV100598353, COSV58574520; called by muse, mutect2, varscan2
- OR5D18 | c.708C>T p.R236= | Silent (SNP) | VAF 97/223 reads (43%) | catalogued as COSV100450930; called by muse, mutect2, varscan2
